Gene-level copy-number profile of tumor specimen TCGA-AF-A56K-01A from TCGA case TCGA-AF-A56K, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIA; Age at diagnosis: 56.2 years (20,527 days).
Specimen TCGA-AF-A56K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.b5939768-e706-43d4-9f3c-b454327bade8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AF-A56K-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/759b7bdd-0897-4ef1-a989-4f6d6b1d3f2b

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 8; copy number 2: 7,262; copy number 3: 35,967; copy number 4: 10,104; copy number 5: 2,472; copy number 6: 1,849; copy number 7: 1,057; copy number 10: 1,035; copy number 12: 16; copy number 13: 32; copy number 25: 16; copy number 26: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AF-A56K-01A-32D-A38W-01): tumor purity 0.55, ploidy 3.34, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,158 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:61,500,556–127,742,951, 973 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr10:77,587,049–80,078,912, 66 genes, copy number 12–26 (within-gene range 3–26) (broad region; genes not listed).
- chr13:26,254,104–27,917,298, 35 genes, copy number 7 (within-gene range 6–7): CDK8, AL159159.1, AL353789.1, WASF3, RPS3AP44, WASF3-AS1, AL159978.1, GPR12, FGFR1OP2P1, AL160035.1, RPS21P8, RPS20P32, USP12, AL158062.1, USP12-AS1, USP12-AS2, LINC02340, LINC00412, RPL21, SNORD102, SNORA27, RASL11A, RNU6-70P, LINC01079, RNY1P1, GTF3A, MTIF3, RNU6-63P, LNX2, POLR1D, AL136439.1, NPM1P4, GSX1, PLUT, RNU6-73P.
- chr13:90,781,766–95,301,475, 49 genes, copy number 7 (within-gene range 6–7): RNU6-75P, LINC00410, BRK1P2, LINC00380, LINC00379, PPIAP23, MIR17HG, MIR17, MIR18A, MIR19A, MIR20A, MIR19B1, MIR92A1, GPC5, AL356118.1, AL162456.1, RNU4ATAC3P, FABP5P4, AL157815.1, GPC5-AS2, AL159152.1, GPC5-IT1, MIR548AS, AL356737.2, AL356737.1, GPC5-AS1, LINC00363, AL354811.2, AL354811.1, GPC6, AL160159.1, HNRNPA1P29, GPC6-AS2, RNA5SP35, GPC6-AS1, DCT, TGDS, GPR180, RNA5SP36, LINC00391, RN7SL585P, SOX21-AS1, SOX21, BRD7P5, RPL21P112, LINC00557, AL139381.1, RNU6-62P, ABCC4.
- chr20:22,220,554–64,313,132, 1,035 genes, copy number 10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 8. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
